Gene-level copy-number profile of tumor specimen TCGA-3B-A9HS-01A from TCGA case TCGA-3B-A9HS, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Myxoid leiomyosarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.1 years (21,946 days).
Specimen TCGA-3B-A9HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e6a7b89c-9cfc-4751-a49e-5d6d9c2c0cac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eda3c97a-fa69-46e2-9ef5-508e68e443ba

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,833; copy number 2: 9,897; copy number 3: 25,471; copy number 4: 16,373; copy number 5: 1,945; copy number 6: 2,180; copy number 7: 747; copy number 8: 611; copy number 9: 190; copy number 10: 3; copy number 11: 19; copy number 12: 11; copy number 13: 6; copy number 14: 55; copy number 17: 5; copy number 18: 3; copy number 19: 24; copy number 20: 19; copy number 21: 23; copy number 22: 6; copy number 23: 24; copy number 24: 27; copy number 25: 62; copy number 26: 5; copy number 27: 42; copy number 28: 30; copy number 29: 1; copy number 30: 12; copy number 31: 7; copy number 33: 1; copy number 34: 33; copy number 35: 12; copy number 36: 39; copy number 37: 11; copy number 39: 10; copy number 41: 29; copy number 43: 5; copy number 47: 5; copy number 48: 4; copy number 51: 2; copy number 53: 1; copy number 54: 2; copy number 59: 1; copy number 61: 1; copy number 62: 14; copy number 66: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HS-01A-11D-A38Y-01): tumor purity 0.57, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,107 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:77,562,416–85,276,632, 103 genes, copy number 7 (broad region; genes not listed).
- chr1:89,995,110–92,014,426, 26 genes, copy number 7: ZNF326, AL161797.1, AC098656.1, RNU6-695P, AL627316.1, LINC02787, SNORD3G, BARHL2, AC092805.1, LINC02609, LINC02788, LINC01763, AC091614.1, PHKA1P1, ZNF644, RPL5P6, HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P, BRDT.
- chr4:31,506,422–85,246,912, 776 genes, copy number 7–8 (broad region; genes not listed).
- chr4:126,431,694–130,432,227, 42 genes, copy number 7 (within-gene range 2–7): AC097528.1, RBM48P1, Y_RNA, AC096773.1, AC093772.1, AC093772.2, AC097462.1, AC097462.2, AC097462.3, INTU, SLC25A31, HSPA4L, AC093591.3, AC093591.1, AC093591.2, PLK4, RNU6-583P, MFSD8, ABHD18, LARP1B, AC099340.1, FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2, LINC02466, LINC02465, EEF1GP8, LINC02479.
- chr4:166,312,935–174,333,380, 90 genes, copy number 8–14 (broad region; genes not listed).
- chr4:174,829,668–177,301,253, 26 genes, copy number 9 (within-gene range 3–9): ADAM29, AC105914.1, AC105914.2, AC022325.1, AC022325.2, AC095050.2, AC095050.1, AC131094.1, TSEN2P1, ADAM20P2, GPM6A, AC097537.1, AC110794.1, MARK2P4, WDR17, AC093605.1, SPATA4, ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509.
- chr5:43,874,367–45,895,970, 17 genes, copy number 7: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr5:159,448,556–160,487,426, 22 genes, copy number 21: LINC01845, AC008703.1, LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A.
- chr5:173,973,779–175,475,378, 23 genes, copy number 8–25: C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634, AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2, ARL2BPP6, DRD1, AC091393.2.
- chr5:178,006,348–179,083,977, 37 genes, copy number 12–26: FAM153CP, AC136632.1, N4BP3, RMND5B, NHP2, AC136632.2, GMCL2, HNRNPAB, PHYKPL, COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1, CLK4, RN7SKP70, AC113348.3, AC113348.1, AC113348.2, ZNF354A, AACSP1, AC126915.2, AC126915.1, AC126915.3, ZNF354B, RNU1-39P, ZFP2, AC104117.1, PIGFP1, AC104117.5, ZNF454, AC104117.3, GRM6, AC104117.4, ZNF879, ZNF354C, AC104117.2.
- chr5:180,416,949–181,342,213, 54 genes, copy number 25: AC034213.1, RNU6-525P, CNOT6, AC122714.1, SCGB3A1, FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:95,504,182–95,632,929, 4 genes, copy number 23: CYCSP17, MANEA-DT, MANEA, AL607077.1.
- chr6:110,391,771–110,967,890, 18 genes, copy number 20: DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6.
- chr6:116,494,989–117,060,799, 12 genes, copy number 7–19 (within-gene range 6–19): TRAPPC3L, CALHM5, CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6, RPS29P13, RNA5SP214.
- chr6:129,157,523–140,898,381, 204 genes, copy number 8–30 (within-gene range 4–30) (broad region; genes not listed).
- chr6:142,748,443–150,510,300, 139 genes, copy number 7–23 (broad region; genes not listed).
- chr6:152,898,047–153,427,154, 11 genes, copy number 19: TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225.
- chr9:69,427,532–72,838,297, 44 genes, copy number 7 (within-gene range 5–7): APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9, TRPM3, RN7SL726P, AL159990.2, AL159990.1, MIR204, PIGUP1, RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15.
- chr12:54,016,931–54,189,008, 15 genes, copy number 24: HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1.
- chr12:57,619,527–57,984,761, 30 genes, copy number 28: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:67,329,014–68,451,663, 22 genes, copy number 24–41 (within-gene range 3–41): AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr12:68,746,125–71,118,247, 49 genes, copy number 36–39: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr12:71,793,855–71,927,248, 4 genes, copy number 14: AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:75,480,753–75,511,636, 3 genes, copy number 48: GLIPR1, AC121761.1, KRR1.
- chr12:76,137,425–76,348,415, 5 genes, copy number 66: AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10.
- chr12:77,129,178–78,213,010, 5 genes, copy number 43 (within-gene range 3–43): AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1.
- chr12:80,561,017–82,515,817, 25 genes, copy number 37–62: AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.
- chr12:85,014,311–87,170,429, 14 genes, copy number 22–41 (within-gene range 2–41): TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68.
- chr12:87,782,163–88,199,887, 11 genes, copy number 34: MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3.
- chr12:91,327,045–91,680,873, 5 genes, copy number 47: LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1.
- chr12:94,148,577–94,307,675, 5 genes, copy number 17 (within-gene range 3–17): PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2.
- chr12:95,996,521–96,400,480, 12 genes, copy number 35: AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1.
- chr12:109,997,419–110,073,686, 6 genes, copy number 31: AC084876.2, ANKRD13A, C12orf76, AC007546.1, AC007546.3, AC007546.2.
- chr12:132,603,150–132,761,832, 10 genes, copy number 7 (within-gene range 2–7): LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1.
- chr17:34,479,272–35,089,319, 11 genes, copy number 7 (within-gene range 4–7): AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL.
- chr17:36,861,674–37,513,501, 19 genes, copy number 34: LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14.
- chr19:94,062–1,812,276, 115 genes, copy number 8 (broad region; genes not listed).
- chr19:7,069,703–7,472,484, 5 genes, copy number 19–51 (within-gene range 6–51): ZNF557, INSR, AC119396.1, AC008878.3, ARHGEF18.
- chr19:10,602,457–10,833,488, 8 genes, copy number 14 (within-gene range 3–14): SLC44A2, ILF3-DT, ILF3, QTRT1, DNM2, MIR638, MIR4748, MIR199A1.
- chr21:13,839,118–15,880,069, 43 genes, copy number 8: ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP.

Autosomal genes at a single copy (total copy number 1): 1,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
